Somatic mutation profile of tumor specimen TCGA-CQ-7064-01A (aliquot TCGA-CQ-7064-01A-11D-2394-08) from TCGA case TCGA-CQ-7064, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 83.9 years (30,640 days).
Specimen TCGA-CQ-7064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea112a03-6272-4ddb-b505-97338a609dab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7064-10A (Blood Derived Normal), aliquot TCGA-CQ-7064-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5b3f5e-43bc-4813-b1be-18d860832a9d

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 26, Nonsense Mutation 8, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2C | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | hotspot (GDC flag); catalogued as rs1283285486, COSV51288537; called by muse, mutect2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2734C>G p.Q912E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV55965528; called by muse, mutect2, varscan2
- ACSBG2 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99397710; called by muse, mutect2, varscan2
- ADCY5 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV100568348; called by muse, mutect2, varscan2
- ARNT2 | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100309621; called by muse, mutect2, varscan2
- AVPR2 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509715; called by muse, varscan2
- AXIN1 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51989044, COSV99250427; called by muse, mutect2, varscan2
- C6 | c.2778A>G p.I926M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99667946; called by muse, mutect2, varscan2
- C8orf74 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766024114, COSV100262486; called by muse, mutect2, varscan2
- CCDC114 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs201978870, COSV100197177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR1 | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.255); catalogued as rs768644917, COSV100259439; called by muse, mutect2, varscan2
- CDK9 | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100953723; called by muse, mutect2, varscan2
- CELSR2 | c.7745C>T p.S2582F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99072298; called by muse, mutect2, varscan2
- CHRD | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV99200770, COSV99200904; called by muse, mutect2, varscan2
- CLDN16 | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV53228245, COSV99290046; called by muse, mutect2, varscan2
- COQ5 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99942567; called by muse, mutect2, varscan2
- COQ5 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV99942569; called by muse, mutect2, varscan2
- CSMD3 | c.3613A>T p.T1205S (on ENST00000297405 / NM_001363185.1; = p.T1101S on NM_052900.3) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99850752; called by muse, mutect2, varscan2
- DAGLA | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs746977362, COSV57197631, COSV99944802; called by muse, mutect2, varscan2
- DHRS3 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100879712; called by muse, mutect2, varscan2
- DHX36 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100274025; called by muse, mutect2, varscan2
- DISP1 | c.2789C>T p.T930I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV99452401; called by muse, mutect2
- DNAH2 | c.2357C>A p.A786E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101209644; called by muse, mutect2, varscan2
- DPP7 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs1176350881, COSV100857448; called by muse, mutect2, varscan2
- EGFLAM | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1333791147, COSV100380899; called by muse, mutect2, varscan2
- ETV1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs959752124, COSV54146379, COSV99624824; called by muse, mutect2, varscan2
- F5 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766643747, COSV100889282; called by muse, mutect2, varscan2
- FAT1 | c.4804G>T p.E1602* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV101499677; called by muse, mutect2
- FCRL4 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 26/141 reads (18%) | catalogued as COSV99620596; called by muse, mutect2, varscan2
- FJX1 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100502797, COSV58553013; called by muse, mutect2
- FSCB | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as rs758200004, COSV100469996; called by muse, varscan2
- GK | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100970691; called by muse, mutect2, varscan2
- H1-2 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV59191103, COSV59192276; called by muse, mutect2, varscan2
- HOXD10 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99983067; called by muse, mutect2, varscan2
- HTR1A | c.758G>C p.S253T | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60501213; called by muse, mutect2, varscan2
- IGFL3 | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100407983; called by muse, mutect2, varscan2
- IKBKE | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV65623465; called by muse, mutect2, varscan2
- KCNH8 | c.77-1G>C p.X26_splice | Splice Site (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100111185; called by muse, mutect2, varscan2
- KCTD8 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100760219; called by muse, varscan2
- KIF15 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs200117192; called by muse, mutect2, varscan2
- KRT12 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866761788, COSV52432390; called by muse, mutect2, varscan2
- LARP7 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV100135372; called by muse, mutect2, varscan2
- LCA5 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs569666879, COSV100878391; called by muse, mutect2, varscan2
- LRRC15 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs767816742, COSV100752980; called by muse, mutect2, varscan2
- LRRC37B | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 50/213 reads (23%) | catalogued as COSV100496581; called by muse, mutect2, varscan2
- MTHFD1 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99387454; called by muse, mutect2, varscan2
- NFKB1 | c.2440G>C p.D814H (on ENST00000394820 / NM_001382627.1; = p.D815H on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as COSV99898000; called by muse, mutect2, varscan2
- NKX2-2 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV65820242; called by muse, mutect2, varscan2
- NLRP14 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100205502; called by muse, mutect2, varscan2
- NNMT | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100248959; called by muse, mutect2, varscan2
- NOD1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99768576; called by muse, mutect2, varscan2
- PCDH8 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132116; called by muse, mutect2, varscan2
- PIGT | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99649285; called by muse, mutect2, varscan2
- PLXNA1 | c.4269G>C p.K1423N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV99304302; called by muse, mutect2, varscan2
- PRKG1 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100907524; called by muse, mutect2, varscan2
- PRSS48 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101490189; called by muse, mutect2, varscan2
- PXDNL | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420658464, COSV100686886; called by muse, mutect2, varscan2
- RNF111 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | catalogued as rs1055168382, COSV62085730; called by muse, mutect2, varscan2
- SCAF1 | c.3438G>T p.M1146I | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100567057, COSV59191222; called by muse, mutect2, varscan2
- SCEL | c.1839G>T p.R613S (on ENST00000349847 / NM_144777.3; = p.R593S on NM_003843.4) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100583301; called by muse, mutect2
- SERPINE1 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1156277677, COSV99776868; called by muse, mutect2, varscan2
- SLC22A6 | c.281C>G p.T94R | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100842959; called by muse, mutect2, varscan2
- SLC25A2 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV99508364; called by muse, mutect2
- SP140 | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100614156; called by muse, mutect2, varscan2
- SPATA17 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100861246; called by muse, mutect2, varscan2
- SYK | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.441); catalogued as rs1237227040, COSV65329269; called by muse, mutect2, varscan2
- TMEM268 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV99938685, COSV99938851; called by muse, mutect2, varscan2
- TNR | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV99692028; called by muse, mutect2, varscan2
- UBR5 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.899); catalogued as COSV99642628; called by muse, mutect2
- WDR35 | c.1730C>T p.T577M (on ENST00000345530 / NM_001006657.2; = p.T566M on NM_020779.4) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs780159239, COSV55602633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.9630T>A p.S3210R (on ENST00000628543; = p.S3385R on NM_152381.6) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99748512; called by muse, mutect2, varscan2
- YTHDF3 | c.846A>T p.K282N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV101572439, COSV72773170; called by muse, mutect2, varscan2
- ZBTB45 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 208/662 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as rs200258269, COSV99564676; called by muse, mutect2, varscan2
- ZNF106 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424434992, COSV99783312; called by muse, mutect2
- ZNF208 | c.1873A>T p.T625S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV101237259, COSV68114423; called by muse, varscan2
- ZNF707 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100690763; called by muse, mutect2
- ZZZ3 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100890473, COSV66234242; called by muse, mutect2, varscan2
- CNTNAP3 | c.1686_1691del p.C562_Q564delinsW | In Frame Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- OR5A1 | c.76_79dup p.Q27Pfs*30 | Frame Shift Ins (INS) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- SPAG4 | c.854_887del p.F285Cfs*27 | Frame Shift Del (DEL) | VAF 17/195 reads (9%) | called by mutect2, pindel
- ABT1 | c.225C>G p.V75= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV99223394; called by muse, mutect2, varscan2
- BEND3 | c.1881C>T p.N627= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs781869180, COSV100944610; called by muse, mutect2, varscan2
- CEACAM7 | c.684C>T p.D228= | Silent (SNP) | VAF 36/246 reads (15%) | catalogued as COSV99137484; called by muse, mutect2, varscan2
- CYP4F2 | c.1530C>A p.G510= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1486329751, COSV99686421; called by muse, mutect2, varscan2
- CYP8B1 | c.423G>A p.E141= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100296338; called by muse, mutect2, varscan2
- EMID1 | c.885T>G p.T295= | Silent (SNP) | VAF 20/304 reads (7%) | catalogued as COSV100469383; called by muse, mutect2
- FUNDC2 | c.210C>T p.F70= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs147164809, COSV65670987; called by muse, mutect2, varscan2
- GPR6 | c.516C>T p.N172= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV99254623; called by muse, mutect2, varscan2
- GRHPR | c.432C>G p.L144= | Silent (SNP) | VAF 25/307 reads (8%) | catalogued as COSV100547172, COSV58943024; called by muse, mutect2
- HECTD4 | c.12435C>T p.F4145= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV101108417; called by muse, mutect2, varscan2
- IGF2R | c.1521G>A p.T507= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs1204426499, COSV100808310, COSV100808347; called by muse, mutect2, varscan2
- MED24 | c.663C>T p.L221= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100673365; called by muse, mutect2, varscan2
- MFSD13A | c.1071C>A p.L357= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV99488104; called by muse, mutect2, varscan2
- MYO1F | c.2380C>A p.R794= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100597162; called by mutect2, varscan2
- NFKBID | c.519C>G p.L173= (on ENST00000396901; = p.L325= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100756550; called by muse, mutect2
- OR10G4 | c.447C>A p.L149= | Silent (SNP) | VAF 68/354 reads (19%) | catalogued as COSV100305039; called by muse, varscan2
- PCDH17 | c.522C>T p.D174= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs141382823, COSV64973098; called by mutect2, varscan2
- RIMS2 | c.3261G>A p.G1087= (on ENST00000666250 / NM_001348490.2; = p.G895= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99211682; called by muse, mutect2, varscan2
- ROS1 | c.453G>A p.P151= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs777706763, COSV63853442; called by muse, mutect2
- SLC12A1 | c.333G>A p.K111= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV100372448, COSV100372621; called by muse, mutect2, varscan2
- SLC4A4 | c.2100C>T p.F700= (on ENST00000264485 / NM_001098484.3; = p.F656= on NM_003759.4) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52624887, COSV99143251; called by muse, mutect2, varscan2
- SLC50A1 | c.57C>G p.T19= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100310522; called by mutect2, varscan2
- SLC9A1 | c.2163G>A p.P721= | Silent (SNP) | VAF 26/419 reads (6%) | catalogued as rs779075735, COSV56055394; called by muse, mutect2
- SPINK5 | c.652C>A p.R218= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as CM013063, COSV99807558; called by muse, mutect2, varscan2
- TTN | c.13098C>T p.S4366= (on ENST00000591111; = p.S4320= on NM_003319.4) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs370208081, COSV59917541; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2
- ZNF546 | c.837G>A p.G279= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100713588; called by muse, mutect2
- HECTD2 | c.600+15A>T | Intron (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99979061; called by muse, mutect2, varscan2
- LINC00482 | n.1110G>T | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
